Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5KO, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5KO-01A (Primary Tumor).

Procedure: L adrenalectomy

Gross description: 7.2 x 6 x 4.8cm, tumor 5.8cm

Diagnosis: adrenocortical carcinoma, 5 per 10 hpf, KI67 20%, focally 30-40%

Reference Pathology:

Diagnosis: adrenocortical carcinoma, KI67 30%

Weiss score: 9

Hough score: 4.89

Van Slooten score: 22.7

ICD-O-3
Carcinoma, adrenal cortical
8370/3
Site: Adrenal Gland, cortex
C74.0
Jan 2/6/13

Source: NCI Genomic Data Commons file 5a7e92c7-c957-4eaf-b02f-ff0463fe3f38 (TCGA-OR-A5KO.B9C848FD-453C-4A56-B625-C4C680790D6A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).